Somatic mutation profile of tumor specimen BA2576D (aliquot aq-BA2576D) from BEATAML1.0 case 2434, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated CEBPA; Tissue or organ of origin: Bone marrow; Age at diagnosis: 28.8 years (10,516 days).
Specimen BA2576D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b729d9c2-ed49-411d-b3f0-3d78fce02e85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2551D (Solid Tissue Normal), aliquot aq-BA2551D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/199c14ab-46ee-4465-b670-8de8aa7cfba6

The open-access MAF lists 20 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, 3'UTR 3, Nonsense Mutation 3, Silent 2, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEBPA | c.931C>T p.Q311* | Nonsense Mutation (SNP) | VAF 26/133 reads (20%) | catalogued as COSV57196030, COSV57199500; called by muse, mutect2, varscan2
- CEBPA | c.341dup p.G116Rfs*54 | Frame Shift Ins (INS) | VAF 4/14 reads (29%) | catalogued as COSV57199438; called by mutect2, varscan2
- CRHR1 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.993); catalogued as rs1217965682; called by muse, mutect2, varscan2
- GATA2 | c.961C>T p.L321F | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62002961, COSV62003975; called by muse, mutect2, varscan2
- SMC1A | c.1756C>T p.R586W | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59128824; called by muse, mutect2, varscan2
- TET2 | c.1630C>T p.R544* | Nonsense Mutation (SNP) | VAF 25/145 reads (17%) | catalogued as rs1440692352, COSV54395690; called by muse, mutect2, varscan2
- ZNF213 | c.410C>T p.S137L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs369876326; called by muse, mutect2, varscan2
- ARNT2 | c.395T>C p.F132S | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- PCDH18 | c.1871A>G p.N624S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.036); called by muse, mutect2
- PTMA | c.172G>T p.E58* (on ENST00000341369 / NM_001099285.2; = p.E57* on NM_002823.5) | Nonsense Mutation (SNP) | VAF 11/71 reads (15%) | called by muse, mutect2, varscan2
- SIGLEC9 | c.548C>A p.T183N | Missense Mutation (SNP) | VAF 3/52 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.374); called by muse, mutect2
- SPATA31D1 | c.4137C>A p.S1379R | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.32); called by muse, mutect2
- WNT5A | c.1085G>T p.C362F | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF821 | c.640G>T p.G214C (on ENST00000425432 / NM_001376297.1; = p.G172C on NM_017530.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2
- DNAAF1 | c.1098C>G p.P366= | Silent (SNP) | VAF 35/182 reads (19%) | called by muse, mutect2, varscan2
- PCDHGA9 | c.246C>A p.G82= | Silent (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- GIMAP6 | c.*48del | 3'UTR (DEL) | VAF 3/20 reads (15%) | called by pindel, varscan2
- IDH1 | c.*4C>G | 3'UTR (SNP) | VAF 34/136 reads (25%) | catalogued as COSV100576157; called by mutect2, varscan2
- NDUFAF7 | c.*32G>A | 3'UTR (SNP) | VAF 31/184 reads (17%) | catalogued as rs749885411; called by muse, mutect2, varscan2
- TTYH1 | chr19:54415289 C>A | 5'Flank (SNP) | VAF 3/41 reads (7%) | catalogued as rs956484807; called by muse, mutect2
